Surgical pathology report (de-identified scan), TCGA case TCGA-91-8497, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-91-8497-01A (Primary Tumor).

[page 1 of 4]
Operative Procedure:
Right da Vinci VATS

Pre-Operative Diagnosis:
Not provided

Post-Operative Diagnosis:
Not provided

Specimen Received:

- A: Level 7 lymph node
- B: Right upper lobe mass
- C: Right upper lobe margin
- D: 4R lymph node
- E: 2R lymph node
- F: Right upper lobe margin #2

Final Pathologic Diagnosis:

A. Lymph node, level VII, biopsy:
One lymph node negative for metastatic carcinoma (0/1).

B. Lung, right upper lobe, resection:

Specimen: Lobe, right upper

Procedure: Wedge resection

Specimen laterality: Right

Tumor site: At parenchymal margin

Specimen integrity: Intact

Tumor size: Invasive component measures less than 1 cm with overall mass measuring 5 cm (see Note)

Tumor focality: Unifocal

Tumor histologic type: Invasive adenocarcinoma associated with mucinous and non-mucinous adenocarcinoma in situ (see Note)

Tumor grade: Low

Visceral pleura invasion: Not identified

Tumor extension: N/A

Margins:

Bronchial margin: N/A

Vascular margin: N/A

Parenchymal margin: Involved by carcinoma

Parietal pleural margin: N/A

Chest wall margin: N/A

Other attached tissue margin: N/A

Treatment effect: N/A

Lymph-vascular invasion: Not identified

Pathologic Staging (pTNM):

[page 2 of 4]
TNM Descriptors:

[m (multiple primary tumors), r (recurrent), y (post-treatment)]

Primary tumor (pT): pT1a

Regional lymph nodes (pN): pN0

Number examined: 3 (specimens A, D and E)

Number involved: 0

If lymph node(s) involved, specify involved nodal station(s): N/A

Distant metastasis (pM): pMX

Additional pathologic findings: Patchy areas of fibrosis

C. Lung, right upper lobe, margin, excision:

Mucinous and non-mucinous adenocarcinoma in situ (2 cm in greatest dimension).

Surgical margin is focally positive for tumor.

Frozen section diagnosis is confirmed.

D. Lymph nodes, 4R, biopsy:

One lymph node negative for metastatic carcinoma (0/1).

E. Lymph node, 2R, biopsy:

Two lymph nodes negative for metastatic carcinoma (0/2).

F. Lung, right upper lobe margin #2, excision:

Benign lung tissue.

Negative for malignancy.

Frozen section diagnosis is confirmed.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Note:

The overall tumor measures 5 cm in greatest dimension; however, the invasive component measures less than 1 cm. This corresponds to pT1a in the current AJCC/TNM staging system.

Intraoperative Consult Diagnosis:

FSB: Right upper lobe mass frozen for diagnosis came in two pieces with a grossly positive margin:

Non-small-cell carcinoma. Favor lung over metastasis.

TAT: 14 mins.

FSC: Right upper lobe margin, new margin:

Surgical margin focally positive. Request additional tissue.

TAT: 12 mins.

FSF: Right upper lobe margin #2:

Surgical margin negative for tumor.

TAT: 17 mins.

[page 3 of 4]
Gross Description:

Received are six separate formalin filled containers each labeled with the patient's name.

Part A is additionally labeled "A, level VII lymph node." The specimen consists of a single fragment of gray-black soft tissue that has dimensions of 1 x 0.8 x 0.3 cm. Submitted in toto in cassette A.

Part B is additionally labeled "B, right upper lobe mass." Please note a portion of this tissue has been banked at the tissue bank and a portion has been sent to diagnostics. The specimen consists of a previously incised and sectioned portion of lung wedge that has overall reconstructed dimensions of 9 x 3.5 x 3.5 cm. The pleural surface ranges from pink-tan, smooth and glistening to purple-red-brown and focally hemorrhagic. Upon sectioning, there is a solid, ill-defined, tan-white mass that has dimensions of 3 x 2.5 x 2 cm. This mass grossly comes to within 0.1 cm from the pleural surface but does not appear grossly to be penetrating the pleura. This mass is grossly present at the stapled surgical margin. A representative section of this mass is taken for frozen section diagnosis and is resubmitted entirely in cassette B1. Additional sections of mass to include pleura are submitted in cassettes B2-3. Sections of tumor to staple line in cassette B4. The uninvolved lung is tan-brown and spongy to focally red, hemorrhagic and congested. No additional lesions are identified within this portion of lung. Representative section of uninvolved lung in cassette B5.

Part C is additionally labeled "C, right upper lobe margin." The specimen consists of a lung wedge that has dimensions of 11 x 2 x 1.5 cm. There is a surgical staple line traversing one aspect of the specimen. The pleura surface ranges from tan-gray, smooth and glistening to red-brown, granular and hemorrhagic. There is an area designated by the surgeon at the time of frozen section as the previous site nearest the tumor. This area is frozen at the time of frozen section and is resubmitted in cassette C1. Additional sectioning of the wedge reveals an ill-defined, tan-brown mass present at the margin. This mass has dimensions of 2 x 1.5 x 0.5 cm. An additional section of this mass is submitted in cassette C2.

Part D is additionally labeled "D, 4R lymph node" and consists of a single fragment of gray-tan fibrofatty soft tissue that has dimensions of 0.4 x 0.3 x 0.2 cm. Submitted in toto in cassette D.

Part E is additionally labeled "E, 2R lymph node" and consists of two fragments of gray-yellow fibrofatty soft tissue that have overall dimensions of 0.8 x 0.5 x 0.3 cm. Submitted in toto in cassette E.

Part F is additionally labeled "F, right upper lobe margin #2, stitch marks margin." The specimen consists of a lung wedge that has dimensions of 5 x 1.5 x 1.5 cm. The pleural surface varies from gray-tan smooth and glistening to gray-brown with focal granularity. There is a staple line traversing one aspect of the specimen. There is a surgical suture to orient the specimen. The specimen

[page 4 of 4]
is inked and the surgical staple line is partially incised at the time of frozen section. The frozen section tissue margin is resubmitted entirely in cassette F1. The remainder of the staple line is trimmed away and the specimen is over-inked with black ink and serially sectioned to reveal a spongy, black-gray cut surface without additional grossly identifiable lesions. Additional representative sections are submitted in cassette F2.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken:

Source: NCI Genomic Data Commons file 8c075d3b-980f-4827-9a18-8357f16c0b05 (TCGA-91-8497.E393A314-6D4D-41F4-A9D3-7D67AB25713B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).